Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A8OD, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A8OD-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Soc. Sec. #:

Physician(s):

Visit #:

Sex: Female

Location:

Accession #:

Service Date:

Received:

Client:

FINAL PATHOLOGIC DIAGNOSIS

A. Bladder, urethra, uterus, ovaries and fallopian tubes, cystectomy, total abdominal hysterectomy and bilateral salpingo-oophorectomy:

1. Invasive urothelial carcinoma, high grade, extending into outer muscularis propria, tumor diameter 2 cm, margins negative for tumor, see comment.

2. Cervix with no significant pathologic abnormality.

- Uterus, endometrium: Sessile polyp.

- Uterus, myometrium: No significant pathologic abnormality.

- Uterus, serosa: No significant pathologic abnormality.

3. Left and right ovaries with no significant pathologic abnormality.

4. Right and left fallopian tubes with no significant pathologic abnormality.

5. Vaginal mucosa with no significant pathologic abnormality.

B. Left pelvic lymph nodes, resection: No tumor in ten lymph nodes (0/10).

C. Right pelvic lymph nodes, resection: No tumor in eleven lymph nodes (0/11).

D. Left distal ureter margin, biopsy: No tumor identified.

E. Final right ureter margin, biopsy: No tumor identified.

COMMENT:

- **Tumor type:** Urothelial carcinoma.

- **Tumor grade:** High grade.

- **Tumor size:** 2 cm (tumor is present in the left superior bladder wall, right dome, and focally on the right superior bladder wall, grossly this distance spans a region of at least 2 cm)

ICD.O.3

Carcinoma, urothelial NOS
8/20/13

Site Bladder NOS 67.9

9/21/2014

[page 2 of 4]
- **Extent of tumor in bladder:** Invasion into outer half of muscularis propria, within 1 mm of peri-vesicular fat.
- **Lymphatic/vascular invasion:** None.
- **Epithelial abnormalities in bladder:** None.
- **Extension of tumor into adjacent organs:** None.
- **Margins:**
- **Urethral margin:** Negative; tumor is greater than 2 cm from margin.
- **Right ureter margin:** Negative; tumor is greater than 2 cm from margin.
- **Left ureter margin:** Negative; tumor is greater than 2 cm from margin.
- **Perivesical margin:** Negative; tumor is 0.4 cm from margin on slide A17.
- **Lymph node status:** Negative, total number of nodes examined: 21.
- **Other pathologic findings in bladder:** None.
- **AJCC/UICC stage:** pT2bN0MX.

Specimen(s) Received

A: Bladder, urethra, uterus, and ovaries, fs
B: Lymph node, left pelvic
C: Lymph node, right pelvic
D: Left distal ureter margin
E: Final right ureter margin

Intraoperative Diagnosis

Urethral margin. biopsy: Benign squamous and urothelial mucosa, no dysplasia or carcinoma.

Clinical History

The patient is a female with a history of invasive urothelial carcinoma of the bladder.

Gross Description

The specimen is received in five parts, labeled with the patient's name and medical record number. Part A is received fresh. Parts B-E are received in formalin.

Part A is additionally labeled "bladder, urethra, uterus and ovaries." The specimen consists of a bladder with an attached uterus, ovaries and vaginal wall. Dimensions of the whole specimen are 14 x 13.5 x 5 cm and the weight is 250 grams. The bladder measures 8 x 6 x 4 cm. The bladder is opened anteriorly over the midline to reveal a tan, folded mucosa with no distinct masses. The right bladder wall contains a brown discolored region, and the posterior wall has a flattened, scarred region. The remainder of the bladder mucosa is unremarkable. The bladder wall thickness measures 1.5 cm. The attached left ureter measures 1.5 x 0.5 cm and is unremarkable. The attached right ureter measures 0.5 x 0.5 cm and is unremarkable. The uterus measures 4 cm from cornu to cornu, 3 cm from anterior to posterior, and 6.5 cm from superior to inferior. The uterus sounds to 5.6 cm. The cervix measures 3.5 x 3 cm, and the os is fish-mouthed and measures 0.8 cm in diameter. The endometrial surface is tan-red and grossly unremarkable with no polyps or masses. The cervical mucosa appears unremarkable. The myometrium and serosa surface appear normal. The right ovary measures 2 x 1.8 x 0.7 cm and has a white, lobulated exterior with a solid yellow interior. The right fallopian tube measures 5 x 0.4 x 0.4 cm and is unremarkable. In the left adnexa there is an attached ovary measuring 2 x 1.5 x 0.6 cm with a white, lobulated appearance and a yellow-white, solid interior. The left fallopian tube measures 6 x 0.3 x 0.3 cm and is unremarkable. The vaginal wall extends from the anterior cervix to the urethral margin and measures 6.5 x 2.5 cm. The wall appears grossly unremarkable. The peri-vesicular fat is thoroughly dissected and no definitive lymph nodes are found. The specimen is inked as follows: The left anterior surface is inked green, the right anterior surface is inked blue, the left anterior midline cut surface is black, the right anterior midline cut surface is green, the anterior surface of the uterus is inked black, and the posterior surface of the uterus is inked blue. The posterior surface of the bladder is inked black. A portion of the bladder is removed for tissue banking. The distal urethral margin is removed and submitted as frozen section diagnosis #1. The frozen section remnant is submitted in cassette A1. The

[page 3 of 4]
remaining cassettes are submitted as follows:

Cassette A2: Posterior cervix.
Cassette A3: Posterior uterus.
Cassette A4: Left ovary.
Cassette A5: Left fallopian tube.
Cassette A6: Anterior cervix.
Cassette A7: Anterior uterus.
Cassette A8: Right ovary.
Cassette A9: Right fallopian tube.
Cassette A10: Left vaginal wall.
Cassette A11: Right vaginal wall.
Cassette A12: Urethral margin, submitted perpendicular, and inferior vaginal wall.
Cassette A13: Left ureter.
Cassette A14: Right ureter.
Cassette A15: Left side of bladder, inferior, black ink is cut surface.
Cassette A16: Left side of bladder, middle, black ink is cut surface.
Cassette A17: Left side of bladder, superior, black ink is cut surface.
Cassette A18: Right side of bladder, inferior.
Cassette A19: Right side of bladder, middle.
Cassette A20: Right side of bladder, superior.
Cassettes A21-A22: Right posterior bladder wall.
Cassettes A23-A24: Left posterior bladder wall.
Cassette A25: Bladder dome.
Cassette A26: Trigone and posterior wall of vagina.
Cassette A27: Candidate perivesicular lymph nodes.

Part B is additionally labeled "left pelvic lymph node." It consists of multiple soft to firm, irregular, bloody, pink-tan-yellow, fatty tissue fragments measuring 6.5 x 4.7 x 1.5 cm in aggregate. The excess fat is trimmed, 14 candidate lymph nodes are found ranging in size between 0.5 x 0.3 x 0.2 cm to 3.5 x 1.2 x 0.5 cm. The specimen is submitted as follows:

Cassettes B1-B2: Largest candidate lymph node cut in half.
Cassette B3: Two candidate lymph nodes.
Cassette B4: One candidate lymph node.
Cassette B5: Two candidate lymph nodes.
Cassette B6: Three candidate lymph nodes.
Cassette B7: Five candidate lymph nodes.

The remaining fatty tissue is returned to the container.

Part C is additionally labeled "right pelvic lymph nodes." It consists of multiple soft to firm, irregular, bloody, pink-tan-yellow, fatty tissue fragments measuring 8.5 x 5.5 x 2 cm in aggregate. The excess fat is trimmed, 12 candidate lymph nodes are found ranging in size between 0.4 x 0.3 x 0.2 cm to 4.2 x 1.5 x 0.5 cm. The specimen is submitted as follows:

Cassettes C1-C2: Largest candidate lymph node cut in half.
Cassette C3: One candidate lymph node.
Cassette C4: One candidate lymph node.
Cassette C5: Three candidate lymph nodes.
Cassette C6: Six candidate lymph nodes.

The remaining fatty tissue is returned to the container.

Part D is additionally labeled "left distal ureter margin." It consists of two soft, tubular pieces of brown-tan tissue. The larger fragment measures 1.4 cm in length and has an average diameter of 0.6 cm. The smaller fragment has a length of 1.3 cm and an average diameter of 0.7 cm. There is a retraction aide at the end of the larger fragment. It is removed and this end is inked blue. The fragments are serially cross sectioned to reveal patent lumen of 0.1 cm in diameter. The specimen is entirely submitted in cassettes D1 and D2 with the larger fragment in cassette D1 and the smaller fragment in cassette D2.

Part E is additionally labeled "final right ureter margin." It consists of a single soft, tubular piece of

[page 4 of 4]
brown-tan tissue measuring 2.5 cm in length and 0.8 cm in average diameter. There is a retraction aide at one end. It is removed and this end is inked blue. The specimen is serially cross sectioned revealing a patent lumen that ranges in diameter between 0.1 cm to 0.3 cm with the largest diameter at the end that is inked blue. The specimen is entirely submitted in cassettes E1 and E2 with the inked end in cassette E1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

/Pathology Resident

Electronically signed out on

Diagnostic Discrepancy		//

Source: NCI Genomic Data Commons file 598615bb-25be-445c-a690-5c8e05947f70 (TCGA-UY-A8OD.B74B0DFB-0A6B-4E4C-A843-50130DE79C1A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).